Gene-level copy-number profile of tumor specimen TCGA-55-A4DF-01A from TCGA case TCGA-55-A4DF, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-55-A4DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.a4853c7f-8d1e-4281-813d-ddf6e9c7c44e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-A4DF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/86526464-1ae0-435a-b00a-b905b54fffaa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,168; copy number 2: 15,003; copy number 3: 25,456; copy number 4: 8,861; copy number 5: 4,197; copy number 6: 1,289; copy number 7: 892; copy number 8: 1,344; copy number 9: 725; copy number 10: 690; copy number 11: 4; copy number 12: 5; copy number 17: 180.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-A4DF-01A-11D-A24C-01): tumor purity 0.42, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,769 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:135,959,275–198,222,513, 1,087 genes, copy number 9–10 (broad region; genes not listed).
- chr4:59,150,924–59,792,114, 5 genes, copy number 12: AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1.
- chr5:58,198–25,716,715, 413 genes, copy number 7–8 (broad region; genes not listed).
- chr5:33,162,179–42,721,878, 150 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr5:155,491,336–156,767,788, 4 genes, copy number 11 (within-gene range 5–11): AC008725.1, RNA5SP199, SGCD, AC011351.1.
- chr9:14,475–43,045,120, 776 genes, copy number 7–8 (broad region; genes not listed).
- chr14:28,936,889–29,372,406, 1 gene, copy number 8 (within-gene range 6–8): AL135878.1.
- chr14:29,210,986–49,913,760, 294 genes, copy number 7–8 (broad region; genes not listed).
- chr14:49,966,399–49,966,511, 1 gene, copy number 7: MIR6076.
- chr14:57,563,920–80,387,757, 501 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr19:20,122,569–20,321,305, 1 gene, copy number 17 (within-gene range 4–17): AC011447.3.
- chr19:20,167,214–24,163,425, 179 genes, copy number 17 (broad region; genes not listed).
- chr19:28,435,388–38,636,955, 357 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,168. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
